Somatic mutation profile of tumor specimen PCProject_0136_T2_WES (aliquot PCProject_0136_T2_WES_1) from CMI case PCProject_0136, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,410 days).
Specimen PCProject_0136_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbc7c6f0-c73f-4d42-af8e-3f01e87774dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0136_SALIVA (DNA), aliquot PCProject_0136_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d23f3c6f-f16e-4862-8971-c9e534adc5cf

The open-access MAF lists 33 somatic variants for this specimen: 18 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 10, 3'UTR 3, Frame Shift Del 3, Intron 1, Nonsense Mutation 1, 5'UTR 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 24/189 reads (13%) | hotspot (GDC flag); catalogued as rs767542615, COSV55758800; called by muse, mutect2, varscan2
- ACAD11 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as rs770146394, COSV99391645; called by muse, varscan2
- SIM1 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs749345383; called by muse, mutect2, varscan2
- TARM1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 7/94 reads (7%) | PolyPhen benign (0); catalogued as rs1394128201; called by muse, varscan2
- ADCY8 | c.3036T>A p.N1012K | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CC2D2A | c.1109A>G p.E370G | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, varscan2
- DRAP1 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- GABRA3 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- HPS5 | c.2093A>T p.N698I (on ENST00000349215 / NM_181507.2; = p.N584I on NM_007216.4) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ILVBL | c.1472-2A>G p.X491_splice | Splice Site (SNP) | VAF 27/202 reads (13%) | called by muse, mutect2, varscan2
- INTS1 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 76/480 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MDH1B | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- NBEAL2 | c.6300del p.W2101Gfs*29 | Frame Shift Del (DEL) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.3436del p.V1146Wfs*33 | Frame Shift Del (DEL) | VAF 51/431 reads (12%) | called by mutect2, pindel, varscan2
- STOM | c.611A>T p.Q204L | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- TDRD6 | c.3841del p.I1281* | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- UNK | c.1498A>T p.N500Y | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZFP28 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- DISP1 | c.2544C>T p.F848= | Silent (SNP) | VAF 38/358 reads (11%) | catalogued as rs755396879, COSV99452126; called by muse, mutect2, varscan2
- GPKOW | c.420C>T p.S140= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs377425815; called by muse, mutect2
- MAGEA3 | c.750C>T p.F250= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs782271747, COSV64756293; called by muse, varscan2
- MAGEA6 | c.276G>A p.E92= | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, varscan2
- NUDT8 | c.243G>A p.T81= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as rs368280015; called by muse, mutect2, varscan2
- PHF3 | c.4851A>G p.R1617= | Silent (SNP) | VAF 17/169 reads (10%) | catalogued as rs748329300; called by muse, mutect2, varscan2
- PPP4R4 | c.114C>G p.L38= | Silent (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- PRPF40A | c.2655A>G p.S885= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as rs1044200797; called by muse, mutect2, varscan2
- SLK | c.240T>A p.I80= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- TRPA1 | c.2208C>T p.L736= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs775284569; called by muse, mutect2, varscan2
- FAM161A | c.*555T>C | 3'UTR (SNP) | VAF 10/96 reads (10%) | catalogued as rs1195163165; called by mutect2, varscan2
- GCH1 | c.-25G>C | 5'UTR (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 6/56 reads (11%) | catalogued as rs1298787056; called by muse, varscan2
- TNFRSF10B | c.*1557A>C | 3'UTR (SNP) | VAF 49/551 reads (9%) | called by muse, mutect2
- TTN | c.10360+3329A>G | Intron (SNP) | VAF 17/163 reads (10%) | catalogued as rs762939059; called by muse, mutect2
